Surgical pathology report (de-identified scan), TCGA case TCGA-33-4538, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4538-01A (Primary Tumor).

1 AL DIAGNOSIS ----- Pathologist: [REDACTED]

1. R4 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

2. BRONCHIAL MARGIN (EXCISION): NEGATIVE FOR TUMOR.

3. STATION 5 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

4-6. L9, STATION 5, L10 LYMPH NODES (EXCISION): ONE (1) LYMPH NODE NEGATIVE FOR TUMOR.

7. LUNG, LEFT UPPER LOBE (LOBECTOMY): INFILTRATING MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (4.8 CM) INVOLVING THE LEFT UPPER LOBAR BRONCHUS. TUMOR EXTENSIVELY ERODES THE BRONCHIAL CARTILAGE AND GROWS INTO THE BRONCHIAL LUMEN AND LUNG. VASCULAR

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4f45f039-3400-4a95-89f6-c0803160e1c7 (TCGA-33-4538.FCC5EDD0-A274-49B7-83C8-EA8DE74B9571.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).